Somatic mutation profile of tumor specimen ALCH-B1XK-TTP1-A (aliquot ALCH-B1XK-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1XK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.6 years (26,134 days).
Specimen ALCH-B1XK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7be49206-9980-498a-b071-635f4379457d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1XK-NB1-A (Blood Derived Normal), aliquot ALCH-B1XK-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/463fe36a-06df-4650-a408-1b77bef9baee

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Nonsense Mutation 5, Intron 2, 3'UTR 1, Splice Site 1, Nonstop Mutation 1, 5'Flank 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 50/365 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABTB2 | c.1499C>T p.T500M | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs757947867, COSV54386399; called by muse, mutect2
- GATA1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs782160624; called by muse, mutect2
- LRRTM1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.411); catalogued as rs200735251, COSV54441121; called by muse, mutect2
- MAGI1 | c.3928G>T p.E1310* | Nonsense Mutation (SNP) | VAF 8/152 reads (5%) | catalogued as COSV100442998; called by muse, mutect2
- MGAT5B | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1458426215; called by muse, mutect2
- MYO18B | c.3761G>A p.R1254H | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs774090650, COSV59124937, COSV59152211; called by muse, mutect2
- NBAS | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775941838, COSV55717633; called by muse, mutect2
- OR1C1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV101376280, COSV68715856; called by muse, mutect2, varscan2
- OR5L1 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 15/247 reads (6%) | catalogued as COSV61733633; called by muse, mutect2
- RNF149 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as COSV54863621; called by muse, mutect2
- SPATA13 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs966369987; called by muse, mutect2
- SSX3 | c.333C>T p.I111= | Splice Region (SNP) | VAF 8/194 reads (4%) | catalogued as rs782204526; called by muse, mutect2
- TNNT1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs376309451; called by muse, mutect2, varscan2
- TNXB | c.9814G>A p.E3272K (on ENST00000647633; = p.E3025K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.354); catalogued as rs1355021413, COSV64482310; called by muse, mutect2
- ABCA13 | c.12793C>T p.R4265W | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ALKBH4 | c.534G>C p.E178D | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- AR | c.1936G>C p.A646P | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2
- ASH2L | c.1554G>T p.L518F | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2
- BBOX1 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2
- CASZ1 | c.235A>T p.S79C | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2
- COL15A1 | c.100+1G>A p.X34_splice | Splice Site (SNP) | VAF 13/199 reads (7%) | called by muse, mutect2
- CRHR2 | c.899C>G p.S300C | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); called by muse, mutect2
- DGKK | c.2271G>T p.K757N | Missense Mutation (SNP) | VAF 31/440 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2
- DNAH10 | c.8342A>G p.D2781G (on ENST00000409039; = p.D2720G on NM_207437.3) | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- EML1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2
- FUS | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2
- GFOD2 | c.715C>T p.L239F | Missense Mutation (SNP) | VAF 24/451 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GOLGA8J | c.655C>A p.L219I | Missense Mutation (SNP) | VAF 20/634 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2
- KRT79 | c.1608G>C p.*536Yext*64 | Nonstop Mutation (SNP) | VAF 29/237 reads (12%) | called by muse, mutect2, varscan2
- LRRC7 | c.2608C>A p.P870T (on ENST00000651989 / NM_001370785.2; = p.P837T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.662); called by muse, mutect2
- NAV3 | c.2260G>T p.G754* | Nonsense Mutation (SNP) | VAF 26/372 reads (7%) | called by muse, mutect2
- NCAM1 | c.1240T>A p.Y414N (on ENST00000316851 / NM_181351.5; = p.Y404N on NM_000615.7) | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- OR8H3 | c.548C>A p.P183Q | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- PHYHIP | c.760C>A p.L254M | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRJ | c.2041G>T p.D681Y | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.197); called by muse, mutect2
- RCN1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 14/280 reads (5%) | called by muse, mutect2
- ROCK1 | c.3809G>A p.R1270K | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SFTPB | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SH3GLB1 | c.735G>T p.M245I | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2
- SLC12A6 | c.2745G>A p.W915* (on ENST00000354181 / NM_001365088.1; = p.W864* on NM_005135.2) | Nonsense Mutation (SNP) | VAF 30/558 reads (5%) | called by muse, mutect2
- SLC18A2 | c.196G>T p.V66L | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- SLC2A10 | c.1547G>T p.R516L | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.253); called by muse, mutect2
- STK11 | c.221_228delinsA p.R74Kfs*20 | Frame Shift Del (DEL) | VAF 20/145 reads (14%) | called by pindel, varscan2*
- TNIK | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- UHRF2 | c.2363A>C p.Q788P | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZBTB20 | c.1346G>A p.S449N (on ENST00000474710 / NM_001164342.2; = p.S376N on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/636 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- ZCCHC2 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARHGEF17 | c.1623G>T p.L541= | Silent (SNP) | VAF 13/325 reads (4%) | called by muse, mutect2
- CLTC | c.2442A>T p.V814= | Silent (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- ENDOU | c.213G>T p.L71= (on ENST00000422538 / NM_001172439.2; = p.L30= on NM_006025.4) | Silent (SNP) | VAF 60/621 reads (10%) | called by muse, mutect2
- FKBP8 | c.849G>A p.L283= (on ENST00000222308 / NM_001308373.2; = p.L284= on NM_012181.5) | Silent (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- GCNA | c.1083C>G p.V361= | Silent (SNP) | VAF 18/301 reads (6%) | called by muse, mutect2
- KRTAP16-1 | c.1197G>T p.P399= | Silent (SNP) | VAF 22/278 reads (8%) | catalogued as rs924643785; called by muse, mutect2
- MAGED1 | c.1689C>T p.L563= | Silent (SNP) | VAF 14/294 reads (5%) | catalogued as rs371683752; called by muse, mutect2
- PRELP | c.852C>G p.P284= | Silent (SNP) | VAF 51/550 reads (9%) | called by muse, mutect2
- RNF213 | c.2205A>T p.L735= | Silent (SNP) | VAF 21/246 reads (9%) | catalogued as COSV60626567; called by muse, mutect2
- SLC38A8 | c.1113C>A p.I371= | Silent (SNP) | VAF 39/264 reads (15%) | catalogued as rs113073498; called by muse, mutect2, varscan2
- YLPM1 | c.4848C>T p.S1616= | Silent (SNP) | VAF 20/340 reads (6%) | catalogued as COSV53120732; called by muse, mutect2
- CEP295 | c.5850+214A>G | Intron (SNP) | VAF 6/164 reads (4%) | catalogued as COSV57348061; called by muse, mutect2
- PHF21A | c.1785+417C>T | Intron (SNP) | VAF 34/393 reads (9%) | catalogued as rs776435846; called by muse, mutect2
- TRHDE | chr12:72271882 C>A | 5'Flank (SNP) | VAF 18/120 reads (15%) | called by muse, varscan2
- ZNF107 | c.*1082G>T | 3'UTR (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
